Somatic mutation profile of tumor specimen C3L-05862-54 (aliquot CPT0342270002) from CPTAC case C3L-05862, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 54.8 years (20,016 days).
Specimen C3L-05862-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5977eae9-ed14-45d4-bc4c-fc9cdfcd81c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05862-50 (Buccal Cell Normal), aliquot CPT0342240001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebc340b8-27cb-4d9f-b07f-6d739389c693

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Frame Shift Ins 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.6232A>G p.K2078E | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1186927156; called by muse, mutect2
- NPAP1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1404920860, COSV61506709, COSV61509654; called by muse, varscan2
- ADGRG6 | c.654dup p.K219Qfs*10 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- CERS6 | c.1002+2_1002+5dup | Frame Shift Ins (INS) | VAF 33/72 reads (46%) | called by mutect2, varscan2
- IL17RC | c.532G>C p.G178R (on ENST00000295981 / NM_153461.4; = p.G107R on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX52 | c.378C>T p.D126= | Silent (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
